Surgical pathology report (de-identified scan), TCGA case TCGA-4X-A9FD, project TCGA-THYM (Thymoma), tissue source site Yale University, specimen TCGA-4X-A9FD-01A (Primary Tumor).

Patient:
MRN:
DOB:
SEX:

- Pathology Report: LYMPH NODE ON PHERNIC/THCase

Provide
Location or Care:

LYMPH NODE ON PHERNIC/THCase

1) LYMPH NODE, "ON PHRENIC", EXCISION:

- TWO LYMPH NODES NEGATIVE FOR TUMOR (0/2)

2) THYMUS, THYMECTOMY:

- THYMOMA, 2.8 CM, WHO TYPE B2
- RESECTION MARGINS NEGATIVE FOR TUMOR, 0.1 CM FROM INKED

RESECTION MARGIN

- NON-NEOPLASTIC THYMUS SHOWS LYMPHOID HYPERPLASIA
- AREA ADJACENT TO INKED "LEFT PHRENIC NERVE MARGIN" SHOWS NO EVIDENCE
OF NERVE

- NINE LYMPH NODES NEGATIVE FOR TUMOR (0/9)

NOTE: This is a largely encapsulated type B2 thymoma. A single section shows extension into adjacent adipose tissue. Yamakawa-Masaoka TNM classification and staging: T2N0

GROSS DESCRIPTION

1) Received fresh labeled with the patient's name and "lymph node on phrenic" is a 0.6 x 0.5 x 0.2 cm aggregate of multiple irregular tan soft tissue fragments which are submitted in toto in one cassette.

2) Received fresh, labeled with the patient's name and "thymus" is a 65 gm, 16 x 14 x 1.8 cm thymectomy specimen that is designated by a long suture marking right superior horn and a short suture marking the left nephric nerve margin. The specimen is inked black, the left nephric margin inked blue and a portion is taken for research and another portion is saved in . The specimen is sectioned to reveal within the left cornu a 2.8 x 2.6 x 0.9 cm encapsulated white-tan mass. The capsule is 0.1 cm in thickness and grossly abuts the inked resection margin. The mass appears to come to within 0.7 cm of the designated left nephric nerve margin. The mass does not appear to invade any of the margins. The remaining thymic parenchyma which is predominantly located within the right lobe is tan-yellow and unremarkable. The specimen is formalin fixed. Representative sections are submitted in seven cassettes as follows: cassettes #1-2=mass with left nephric margin, cassettes #3-5=mass, cassette #6=uninvolved right lobe and cassette #7=uninvolved right horn. Gross photographs are taken.

Signed by Pathologist:

Signed before import by
Filed automatically on

ICD O-3
Thymoma, type B2,
malignant 8584/3
Site: Thymus C37.9
JW 6/24/14

Source: NCI Genomic Data Commons file 09263c07-77ea-40f1-bc72-0d219125951d (TCGA-4X-A9FD.E701DA21-9B43-49C9-8B9A-5B2DC2803C14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).